TCGA case TCGA-39-5040 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eca4bfa2-5ba5-4708-959a-d901c1b61edd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Dead; Days to death: 519 days (1.4 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 59.7 years (21,790 days); Year of diagnosis: 2008; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 24 days; Number of cycles: 1; Treatment dose: 160 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 92 days; Number of cycles: 3; Treatment dose: 600 mg; Prescribed dose: 5; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 92 days; Number of cycles: 3; Treatment dose: 360 mg; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 129 days; Days to treatment end: 164 days; Treatment dose: 5,000 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Initial disease status: Recurrent Disease; Days to treatment start: 448 days (1.2 years); Days to treatment end: 476 days (1.3 years); Number of cycles: 3; Treatment dose: 850 mg; Prescribed dose: 400; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Recurrent Disease; Days to treatment start: 448 days (1.2 years); Days to treatment end: 476 days (1.3 years); Number of cycles: 3; Treatment dose: 2,100 mg; Prescribed dose: 1000; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine; Initial disease status: Recurrent Disease; Days to treatment start: 448 days (1.2 years); Days to treatment end: 476 days (1.3 years); Number of cycles: 3; Treatment dose: 50 mg; Prescribed dose: 25; Prescribed dose units: mg/m2; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 60.9 years (22,232 days); Days to diagnosis: 442 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 442 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 519 days (1.4 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 80; FEV1/FVC before bronchodilator (%): 93; FEV1 before bronchodilator (% of reference): 97.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 60; Tobacco smoking onset year: 1964; Tobacco smoking quit year: 2005.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-39-5040-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1.5; Shortest dimension: 0.4.
  Slide TCGA-39-5040-01A-02-BS2: Section location: Bottom; Percent tumor cells: 35; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 30; Percent stromal cells: 25.
  Slide TCGA-39-5040-01A-01-BS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 40; Percent stromal cells: 15.
- Sample TCGA-39-5040-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-39-5040-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Performance status timing: Preoperative; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2.
- Drug treatment 3: Regimen number: 1; Therapy regimen: Recurrence.
- Drug treatment 4: Regimen number: 3; Therapy regimen: Recurrence.
- Follow-up form: Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Progressive Disease; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 519 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 519 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 442 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-39-5040-01A-21D-2121-01): tumor purity 0.59, ploidy 3.04, whole-genome doublings 1.
